MMRF case MMRF_2258 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/5ce83d2f-4e92-4c21-95a2-d0ca5f58f466

Demographics
Sex at birth: female; Race: white; Ethnicity: hispanic or latino; Age at index: 74 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 74.5 years (27,200 days); ISS stage: III; Days to last known disease status: 826 days (2.3 years); Days to last follow up: 826 days (2.3 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 112 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -11 (ECOG 1): M Protein 1.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 29.7 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.27 mg/dL; Immunoglobulin G 15.4 g/L; Immunoglobulin A 0.36 g/L; Immunoglobulin M 0.2 g/L; Beta 2 Microglobulin 11.8 µg/mL; Hemoglobin 5.27 mmol/L; Leukocytes 4.74 ×10⁹/L; Absolute Neutrophil 3.07 ×10⁹/L; Platelets 115 ×10⁹/L; Creatinine 398 µmol/L; Blood Urea Nitrogen 23.9 mmol/L; Calcium 2.2 mmol/L; Albumin 38 g/L; Total Protein 6.6 g/dL; Glucose 5.67 mmol/L.
- Day 84 (ECOG 1): M Protein 0.8 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 16.2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.36 mg/dL; Immunoglobulin G 11.1 g/L; Immunoglobulin A 0.3 g/L; Immunoglobulin M 0.2 g/L; Beta 2 Microglobulin 15.9 µg/mL; Hemoglobin 8.31 mmol/L; Leukocytes 8.41 ×10⁹/L; Absolute Neutrophil 5.88 ×10⁹/L; Platelets 158 ×10⁹/L; Creatinine 362 µmol/L; Blood Urea Nitrogen 18.9 mmol/L; Calcium 2.18 mmol/L; Albumin 37 g/L; Total Protein 6.1 g/dL; Glucose 6.11 mmol/L.
- Day 154 (ECOG 1): M Protein 0.8 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 19 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 4.06 mg/dL; Immunoglobulin G 12.3 g/L; Immunoglobulin A 0.56 g/L; Immunoglobulin M 0.2 g/L; Beta 2 Microglobulin 14.6 µg/mL; Hemoglobin 7.01 mmol/L; Leukocytes 10.2 ×10⁹/L; Absolute Neutrophil 7.32 ×10⁹/L; Platelets 163 ×10⁹/L; Creatinine 345 µmol/L; Blood Urea Nitrogen 14.3 mmol/L; Calcium 2.13 mmol/L; Albumin 40 g/L; Total Protein 6.4 g/dL; Glucose 9.02 mmol/L.
- Day 238 (ECOG 1): M Protein 1.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 32.4 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.02 mg/dL; Immunoglobulin G 15.8 g/L; Immunoglobulin A 0.47 g/L; Immunoglobulin M 0.2 g/L; Beta 2 Microglobulin 15.8 µg/mL; Hemoglobin 7.69 mmol/L; Leukocytes 8.85 ×10⁹/L; Absolute Neutrophil 6.33 ×10⁹/L; Platelets 158 ×10⁹/L; Creatinine 407 µmol/L; Blood Urea Nitrogen 18.6 mmol/L; Calcium 2.23 mmol/L; Albumin 41 g/L; Total Protein 7 g/dL; Glucose 14.4 mmol/L.
- Day 331 (ECOG 1): M Protein 1.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 46 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 4.73 mg/dL; Immunoglobulin G 16.7 g/L; Immunoglobulin A 0.36 g/L; Immunoglobulin M 0.26 g/L; Beta 2 Microglobulin 24.6 µg/mL; Hemoglobin 8.56 mmol/L; Leukocytes 5.6 ×10⁹/L; Absolute Neutrophil 2.87 ×10⁹/L; Platelets 200 ×10⁹/L; Creatinine 345 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.05 mmol/L; Albumin 43 g/L; Total Protein 7.5 g/dL; Glucose 7.54 mmol/L.
- Day 421 (ECOG 1): M Protein 1.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 90.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 8.72 mg/dL; Immunoglobulin G 20 g/L; Immunoglobulin A 0.36 g/L; Immunoglobulin M 0.27 g/L; Hemoglobin 7.32 mmol/L; Leukocytes 5.71 ×10⁹/L; Absolute Neutrophil 3.14 ×10⁹/L; Platelets 175 ×10⁹/L; Creatinine 566 µmol/L; Blood Urea Nitrogen 16.4 mmol/L; Calcium 2.08 mmol/L; Albumin 40 g/L; Total Protein 7.3 g/dL; Glucose 6 mmol/L.
- Day 525: M Protein 1.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 50.3 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 6.46 mg/dL; Immunoglobulin G 18.2 g/L; Immunoglobulin A 0.35 g/L; Immunoglobulin M 0.24 g/L; Beta 2 Microglobulin 27.2 µg/mL; Hemoglobin 7.5 mmol/L; Leukocytes 6.88 ×10⁹/L; Absolute Neutrophil 4.97 ×10⁹/L; Platelets 148 ×10⁹/L; Creatinine 610 µmol/L; Blood Urea Nitrogen 19.6 mmol/L; Calcium 2.2 mmol/L; Albumin 44 g/L; Total Protein 7.8 g/dL; Glucose 6.66 mmol/L.
- Day 639: Serum Free Immunoglobulin Light Chain, Kappa 45.5 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 4.47 mg/dL; Immunoglobulin G 18.5 g/L; Immunoglobulin A 0.32 g/L; Immunoglobulin M 0.2 g/L; Beta 2 Microglobulin 26.5 µg/mL; Hemoglobin 6.7 mmol/L; Leukocytes 4.93 ×10⁹/L; Absolute Neutrophil 2.4 ×10⁹/L; Platelets 195 ×10⁹/L; Creatinine 575 µmol/L; Blood Urea Nitrogen 13.2 mmol/L; Calcium 2.18 mmol/L; Albumin 44 g/L; Total Protein 7.7 g/dL; Glucose 4.79 mmol/L.
- Day 826 (ECOG 1): M Protein 1.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 66.3 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 4.84 mg/dL; Immunoglobulin G 20.7 g/L; Immunoglobulin A 0.32 g/L; Immunoglobulin M 0.22 g/L; Beta 2 Microglobulin 28 µg/mL; Hemoglobin 7.32 mmol/L; Leukocytes 6.52 ×10⁹/L; Absolute Neutrophil 4.01 ×10⁹/L; Platelets 194 ×10⁹/L; Creatinine 610 µmol/L; Blood Urea Nitrogen 18.2 mmol/L; Calcium 2.23 mmol/L; Albumin 44 g/L; Total Protein 8.1 g/dL; Glucose 7.65 mmol/L.

Other clinical attributes
- Day -11: Weight: 68 kg; Height: 157 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_2258_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -11 days.
- Sample MMRF_2258_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -11 days.
